Somatic mutation profile of tumor specimen HTMCP-03-06-02356-01A (aliquot HTMCP-03-06-02356-01A-01D-9392) from CGCI case HTMCP-03-06-02356, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 40.6 years (14,842 days).
Specimen HTMCP-03-06-02356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 517d1459-bc2c-46f3-9361-19a4f96fd101.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02356-10A (Blood Derived Normal), aliquot HTMCP-03-06-02356-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12245b12-9b53-48c8-8ef6-3dfaf549abde

The open-access MAF lists 40 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Splice Site 1, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV67127677; called by muse, mutect2, varscan2
- ADAMTS9 | c.5630A>G p.N1877S | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs1421783701; called by muse, mutect2, varscan2
- AMPH | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 69/293 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs747570486, COSV57741545; called by muse, mutect2, varscan2
- BCOR | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100652778, COSV60706829; called by muse, mutect2, varscan2
- CACNA1A | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs369084322; called by mutect2, varscan2
- CCND2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as rs1345554353, COSV99713914, COSV99714229; called by muse, mutect2, varscan2
- CSMD3 | c.10138A>C p.K3380Q (on ENST00000297405 / NM_001363185.1; = p.K3211Q on NM_052900.3) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1343934575, COSV52134873; called by muse, mutect2, varscan2
- DSP | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 109/143 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs397516916, COSV101131405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.11735C>T p.A3912V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs1192626563; called by muse, mutect2, varscan2
- MYOCD | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28730822; called by muse, mutect2, varscan2
- NFE2L2 | c.110T>C p.F37S | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67962819; called by muse, mutect2, varscan2
- SEPTIN12 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1027155568, COSV51619339; called by muse, mutect2, varscan2
- SLC6A5 | c.641T>A p.V214D | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54229521; called by muse, mutect2, varscan2
- TTLL13P | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs375262244; called by muse, mutect2, varscan2
- WDFY3 | c.5332G>A p.A1778T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV55696935; called by muse, mutect2, varscan2
- ZFHX4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.734); catalogued as COSV51465610; called by muse, mutect2, varscan2
- ZNF804A | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56434436; called by muse, mutect2, varscan2
- ADAMTS17 | c.1712A>G p.D571G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ADAMTS17 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- CIP2A | c.1999C>G p.Q667E | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CSMD3 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DNAH3 | c.5079T>G p.I1693M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E4F1 | c.2108C>A p.P703Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- FAT3 | c.2337G>C p.E779D | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FOCAD | c.5011G>T p.D1671Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HS3ST5 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KNL1 | c.5587_5593+24del p.X1863_splice (on ENST00000346991 / NM_170589.5; = p.X1837_splice on NM_144508.5) | Splice Site (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- MYH15 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYH15 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, varscan2
- STK11 | c.819del p.I274Sfs*13 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by pindel, varscan2
- WDFY3 | c.6352G>A p.D2118N | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- YLPM1 | c.5081C>T p.P1694L | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ARHGAP31 | c.1485G>A p.P495= | Silent (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- CUBN | c.195C>T p.T65= | Silent (SNP) | VAF 51/142 reads (36%) | catalogued as rs373954380; called by muse, mutect2, varscan2
- ESPL1 | c.2020C>T p.L674= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- LRRC1 | c.96C>T p.Y32= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1412688993; called by muse, mutect2
- MAP3K11 | c.693C>T p.C231= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- SH3RF3 | c.835C>T p.L279= | Silent (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- ZNF423 | c.2940G>T p.L980= (on ENST00000563137 / NM_001379286.1; = p.L972= on NM_015069.4) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV52175668; called by muse, mutect2, varscan2
- AC133485.7 | n.4662G>A | RNA (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
